Somatic mutation profile of tumor specimen MMRF_2378_1_BM_CD138pos (aliquot MMRF_2378_1_BM_CD138pos_T2_KHS5U_K14047) from MMRF case MMRF_2378, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.9 years (24,441 days).
Specimen MMRF_2378_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ec79b70-e216-4f8b-9078-5bad37ee9c93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2378_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2378_1_PB_Whole_C1_KHS5U_K14046; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de74f2ab-e1e0-4a5e-a4d8-c4d00ab49ca8

The open-access MAF lists 157 somatic variants for this specimen: 68 protein-altering or splice-affecting, 8 silent, 81 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, 3'UTR 46, Intron 22, Silent 8, 5'UTR 5, 5'Flank 4, Splice Site 4, Nonsense Mutation 2, 3'Flank 2, RNA 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 26/226 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 34/230 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ARC | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs754781408; called by muse, mutect2
- C3 | c.3370G>A p.V1124M | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1280952198, COSV99837338; called by muse, mutect2
- CR2 | c.2479G>A p.V827M | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.559); catalogued as rs748038018, COSV65507153; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLG4 | c.875G>T p.R292L (on ENST00000399506 / NM_001321075.3; = p.R335L on NM_001365.4) | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.066); catalogued as COSV57238028; called by muse, mutect2, varscan2
- ELP1 | c.3517G>T p.V1173L | Missense Mutation (SNP) | VAF 104/300 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs771339771, COSV65897752; called by muse, mutect2, varscan2
- GRAMD1B | c.2173G>T p.D725Y | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV59204216, COSV99074529; called by muse, mutect2
- GRIN2B | c.3232G>A p.A1078T | Missense Mutation (SNP) | VAF 134/257 reads (52%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.31); catalogued as rs756076031, COSV74206215; called by muse, mutect2, varscan2
- IGDCC4 | c.3580C>A p.P1194T | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs1567077925; called by muse, mutect2, varscan2
- IGHV3-74 | c.8T>G p.F3C | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); catalogued as rs773935518; called by muse, varscan2
- IGKV1D-8 | c.212A>T p.Y71F | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs756235837; called by muse, mutect2, varscan2
- IGLV3-1 | c.238T>C p.F80L | Missense Mutation (SNP) | VAF 66/69 reads (96%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs561290535; called by muse, mutect2, varscan2
- INTS2 | c.2420G>A p.R807Q | Missense Mutation (SNP) | VAF 142/282 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV99248416; called by muse, mutect2, varscan2
- KCNQ1 | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 80/289 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs199473482, CM045296; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- KIF4A | c.2954G>A p.R985Q | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763886186, COSV65541329; called by muse, mutect2, varscan2
- KLHL6 | c.286T>G p.Y96D | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58067396; called by muse, mutect2, varscan2
- MCIDAS | c.811A>G p.S271G | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as COSV101563751; called by muse, mutect2, varscan2
- NELL2 | c.1637G>T p.G546V | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV61575226; called by muse, mutect2, varscan2
- NKX1-1 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.18); catalogued as rs1203384788; called by muse, mutect2, varscan2
- OR52K2 | c.45G>T p.L15F | Missense Mutation (SNP) | VAF 44/393 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.424); catalogued as rs749364614; called by muse, mutect2, varscan2
- PCNX2 | c.905A>G p.K302R | Missense Mutation (SNP) | VAF 69/143 reads (48%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs1376776873; called by muse, mutect2, varscan2
- TMEM19 | c.103A>T p.I35L | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV57001355; called by muse, mutect2, varscan2
- WNK1 | c.1457G>T p.R486L | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60026815, COSV60033505; called by muse, mutect2
- ZNF541 | c.1076A>G p.E359G | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs1339419195; called by mutect2, varscan2
- ALG10 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 47/274 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ARHGEF11 | c.4321G>A p.D1441N | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BTBD18 | c.1432T>C p.C478R | Missense Mutation (SNP) | VAF 82/221 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- CCDC148 | c.765-2A>C p.X255_splice | Splice Site (SNP) | VAF 13/123 reads (11%) | called by muse, mutect2, varscan2
- CCDC66 | c.2270C>T p.S757L (on ENST00000394672 / NM_001353147.1; = p.S723L on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP73 | c.162G>C p.E54D | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- CRTC1 | c.1060T>C p.F354L | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSMD3 | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 44/44 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CZIB | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 72/307 reads (23%) | called by muse, mutect2, varscan2
- DGKK | c.3436G>C p.V1146L | Missense Mutation (SNP) | VAF 71/71 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- DNAH2 | c.10828T>C p.C3610R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- EDIL3 | c.577T>A p.Y193N | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- EIF2D | c.143T>C p.L48P | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- FADS2 | c.1040_1077+7del p.X347_splice | Splice Site (DEL) | VAF 16/210 reads (8%) | called by mutect2, pindel
- FXR2 | c.1107+1G>C p.X369_splice | Splice Site (SNP) | VAF 54/130 reads (42%) | called by muse, mutect2, varscan2
- HCST | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- HIPK3 | c.3131T>G p.L1044W | Missense Mutation (SNP) | VAF 27/287 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.541); called by muse, mutect2
- HP1BP3 | c.357A>C p.K119N | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2
- ITGA2B | c.1038G>T p.E346D | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.029); called by muse, mutect2
- KIF13A | c.4111G>T p.A1371S | Missense Mutation (SNP) | VAF 23/426 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.186); called by muse, mutect2
- KLRK1 | c.44T>A p.M15K | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- KPNA7 | c.1029G>T p.K343N | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KRT15 | c.1177C>T p.L393F | Missense Mutation (SNP) | VAF 129/293 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LARP1B | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LLGL1 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 89/208 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- LRRC1 | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 73/147 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NSUN3 | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 21/185 reads (11%) | called by muse, mutect2, varscan2
- OR10W1 | c.184A>T p.I62L | Missense Mutation (SNP) | VAF 57/391 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR1A2 | c.678A>T p.Q226H | Missense Mutation (SNP) | VAF 69/327 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PDE7B | c.458T>A p.V153E | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- PREX2 | c.47A>T p.D16V | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- PRKCE | c.1341_1352del p.D448_D451del | In Frame Del (DEL) | VAF 45/191 reads (24%) | called by mutect2, pindel, varscan2
- RELN | c.7529C>T p.P2510L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SHANK1 | c.2906C>A p.S969Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC28A2 | c.1747+3A>T | Splice Region (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- SMCHD1 | c.4826T>C p.L1609P | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- STRN4 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); called by muse, mutect2
- TRGV9 | c.179A>T p.E60V | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- TRIM32 | c.1595_1620del p.G532Afs*3 | Frame Shift Del (DEL) | VAF 89/413 reads (22%) | called by mutect2, pindel
- TTN | c.56734A>G p.N18912D (on ENST00000591111; = p.N11488D on NM_003319.4) | Missense Mutation (SNP) | VAF 20/204 reads (10%) | PolyPhen probably damaging (0.994); called by muse, mutect2
- VAV1 | c.1358A>G p.Q453R | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- VSIG2 | c.706+1G>T p.X236_splice | Splice Site (SNP) | VAF 26/300 reads (9%) | called by muse, mutect2
- WDR31 | c.766G>A p.G256S (on ENST00000374193 / NM_001006615.3; = p.G255S on NM_145241.5) | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCGBP | c.11643G>A p.A3881= | Silent (SNP) | VAF 23/518 reads (4%) | catalogued as rs748256686; called by muse, mutect2
- IGF2BP1 | c.1143C>T p.S381= | Silent (SNP) | VAF 55/89 reads (62%) | catalogued as rs142951853; called by muse, mutect2, varscan2
- LCNL1 | c.279C>T p.G93= | Silent (SNP) | VAF 76/307 reads (25%) | catalogued as rs373222792; called by muse, mutect2, varscan2
- MGAT4D | c.222T>A p.I74= | Silent (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- MMP13 | c.127C>T p.L43= | Silent (SNP) | VAF 10/337 reads (3%) | called by muse, mutect2
- NOD1 | c.1917G>A p.Q639= | Silent (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2
- SHANK1 | c.2907C>A p.S969= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- SPATA31E1 | c.3513A>T p.L1171= | Silent (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
- ACAN | c.2027-587C>G | Intron (SNP) | VAF 30/360 reads (8%) | called by muse, mutect2
- AGPAT3 | c.*1482A>T | 3'UTR (SNP) | VAF 57/181 reads (31%) | called by muse, mutect2, varscan2
- ANK1 | c.5395-192A>C | Intron (SNP) | VAF 30/31 reads (97%) | called by muse, mutect2, varscan2
- ANO5 | c.*370C>T | 3'UTR (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- APBB3 | c.291-24C>T | Intron (SNP) | VAF 28/152 reads (18%) | catalogued as rs555756503; called by muse, mutect2, varscan2
- ARHGAP20 | c.105+455C>T | Intron (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- ART4 | c.*1A>G | 3'UTR (SNP) | VAF 53/290 reads (18%) | called by muse, mutect2, varscan2
- ATP5MC3 | c.-114G>T | 5'UTR (SNP) | VAF 28/49 reads (57%) | called by muse, mutect2, varscan2
- BCL2 | c.*5165A>T | 3'UTR (SNP) | VAF 34/126 reads (27%) | called by muse, mutect2, varscan2
- BCL2 | c.*4395_*4408del | 3'UTR (DEL) | VAF 17/151 reads (11%) | called by mutect2, pindel
- CELA3A | chr1:21998510 C>G | 5'Flank (SNP) | VAF 5/95 reads (5%) | called by muse, mutect2
- CHRM2 | c.-47+33810G>A | Intron (SNP) | VAF 40/72 reads (56%) | catalogued as rs1245130086, COSV57786126; called by muse, mutect2, varscan2
- CRISPLD1 | c.*1061T>A | 3'UTR (SNP) | VAF 14/106 reads (13%) | called by mutect2, varscan2
- CSGALNACT1 | c.*520_*523del | 3'UTR (DEL) | VAF 20/90 reads (22%) | catalogued as rs899760614; called by mutect2, pindel, varscan2
- CSPG5 | c.-1161G>A | 5'UTR (SNP) | VAF 9/153 reads (6%) | called by muse, mutect2
- DHX33 | c.*437G>A | 3'UTR (SNP) | VAF 24/113 reads (21%) | called by muse, mutect2, varscan2
- DPF3 | c.871+3077C>T | Intron (SNP) | VAF 11/152 reads (7%) | called by muse, mutect2
- ECEL1 | c.*197_*228del | 3'UTR (DEL) | VAF 20/206 reads (10%) | called by mutect2, pindel
- F13B | c.-4G>A | 5'UTR (SNP) | VAF 34/178 reads (19%) | catalogued as COSV100803272; called by muse, mutect2, varscan2
- FAM177B | c.242-445C>T | Intron (SNP) | VAF 22/242 reads (9%) | called by muse, mutect2
- FASLG | c.*304G>T | 3'UTR (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- FBXL7 | c.*1306G>C | 3'UTR (SNP) | VAF 36/57 reads (63%) | called by muse, mutect2, varscan2
- GALC | c.*1114A>G | 3'UTR (SNP) | VAF 19/29 reads (66%) | catalogued as rs1299081059; called by muse, mutect2, varscan2
- HAUS6 | c.2806+489A>C | Intron (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- HIGD2B | c.*71C>A | 3'UTR (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- HTR2A | c.*1162G>A | 3'UTR (SNP) | VAF 12/13 reads (92%) | catalogued as rs1299334335; called by muse, mutect2, varscan2
- IL1R1 | c.1303+58G>A | Intron (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- KCNK12 | c.*8432T>G | 3'UTR (SNP) | VAF 48/122 reads (39%) | called by muse, mutect2, varscan2
- KIF1B | c.2115+7339C>T | Intron (SNP) | VAF 22/196 reads (11%) | called by muse, mutect2, varscan2
- KRTAP22-1 | c.*98C>T | 3'UTR (SNP) | VAF 89/179 reads (50%) | called by muse, mutect2, varscan2
- LINC02860 | n.447C>T | RNA (SNP) | VAF 97/167 reads (58%) | called by muse, mutect2, varscan2
- MIB1 | c.*3753C>A | 3'UTR (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- MOB3B | c.*3128A>C | 3'UTR (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- MSL3 | c.1171+995G>T | Intron (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- MTMR2 | c.*725C>T | 3'UTR (SNP) | VAF 18/185 reads (10%) | catalogued as rs909424387; called by muse, mutect2
- MTO1 | chr6:73461738 T>A | 5'Flank (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
- MVK | c.-88G>C | 5'UTR (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- NACC2 | c.*4379T>C | 3'UTR (SNP) | VAF 25/478 reads (5%) | called by muse, mutect2
- NEDD9 | c.460-7331G>A | Intron (SNP) | VAF 132/533 reads (25%) | called by muse, mutect2, varscan2
- NEIL1 | c.435-142T>C | Intron (SNP) | VAF 5/104 reads (5%) | catalogued as rs1045184176; called by muse, mutect2
- NFAM1 | c.*1338G>A | 3'UTR (SNP) | VAF 10/36 reads (28%) | catalogued as rs761410910; called by muse, mutect2, varscan2
- NPAP1 | c.*3369A>G | 3'UTR (SNP) | VAF 20/218 reads (9%) | catalogued as COSV100275715; called by muse, mutect2
- NPY1R | c.*1172C>A | 3'UTR (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2
- NRXN1 | c.3365-110825A>G | Intron (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2
- NTRK1 | c.359+84A>C | Intron (SNP) | VAF 39/40 reads (98%) | called by muse, mutect2, varscan2
- NUCKS1 | c.*3573T>C | 3'UTR (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2, varscan2
- OLFML2A | c.*3798C>T | 3'UTR (SNP) | VAF 28/101 reads (28%) | called by muse, mutect2, varscan2
- OR2A13P | n.873G>A | RNA (SNP) | VAF 40/242 reads (17%) | called by muse, mutect2, varscan2
- PAQR8 | c.*1225C>T | 3'UTR (SNP) | VAF 4/73 reads (5%) | catalogued as rs913394316; called by muse, mutect2
- PIK3R5 | c.*842T>C | 3'UTR (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- PRRC1 | c.*1244_*1261del | 3'UTR (DEL) | VAF 55/103 reads (53%) | called by mutect2, pindel, varscan2
- RSPH14 | c.303-2059G>T | Intron (SNP) | VAF 27/78 reads (35%) | called by muse, mutect2, varscan2
- RTP2 | c.-96T>C | 5'UTR (SNP) | VAF 59/102 reads (58%) | called by muse, mutect2, varscan2
- S100A7A | chr1:153421672 A>C | 3'Flank (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2
- SGCE | c.*74C>T | 3'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- SMAD7 | c.*871T>G | 3'UTR (SNP) | VAF 52/189 reads (28%) | called by muse, mutect2, varscan2
- SMARCD1 | c.*526A>T | 3'UTR (SNP) | VAF 10/172 reads (6%) | called by muse, mutect2
- SMOC2 | c.*793C>T | 3'UTR (SNP) | VAF 3/36 reads (8%) | catalogued as rs1018048392; called by muse, mutect2
- SPTSSA | c.*602A>G | 3'UTR (SNP) | VAF 19/131 reads (15%) | called by muse, mutect2, varscan2
- SRCIN1 | c.3519+692A>T | Intron (SNP) | VAF 102/193 reads (53%) | called by muse, mutect2, varscan2
- ST6GAL1 | c.*944_*945del | 3'UTR (DEL) | VAF 61/134 reads (46%) | called by mutect2, pindel, varscan2
- STK33 | c.-161-140T>C | Intron (SNP) | VAF 32/88 reads (36%) | called by muse, mutect2, varscan2
- TEAD1 | c.*4029A>C | 3'UTR (SNP) | VAF 21/179 reads (12%) | called by muse, mutect2, varscan2
- TEKT4 | c.498+36G>A | Intron (SNP) | VAF 11/19 reads (58%) | catalogued as rs782730743; called by muse, mutect2, varscan2
- TMBIM4 | c.97+792C>G | Intron (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- TNS3 | c.4193+404C>T | Intron (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- TPD52L1 | c.*865C>A | 3'UTR (SNP) | VAF 12/17 reads (71%) | called by muse, mutect2
- TRDN | c.*840G>A | 3'UTR (SNP) | VAF 21/34 reads (62%) | called by muse, mutect2, varscan2
- TRIM7 | c.*9G>A | 3'UTR (SNP) | VAF 33/95 reads (35%) | catalogued as rs1415584237; called by muse, mutect2, varscan2
- TUBGCP4 | c.1065+109_1065+139del | Intron (DEL) | VAF 24/264 reads (9%) | called by mutect2, pindel
- TXNDC9 | c.*192G>T | 3'UTR (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- USP34 | chr2:61185628 T>G | 3'Flank (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- USP48 | chr1:21783314 C>T | 5'Flank (SNP) | VAF 54/286 reads (19%) | catalogued as rs1231251260, COSV57607821; called by muse, mutect2, varscan2
- VEPH1 | c.*975A>T | 3'UTR (SNP) | VAF 11/128 reads (9%) | called by muse, mutect2
- VGLL3 | c.*2244G>A | 3'UTR (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2
- WNT7A | c.*2C>T | 3'UTR (SNP) | VAF 30/54 reads (56%) | called by muse, mutect2, varscan2
- YAP1 | c.*582A>T | 3'UTR (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- ZFP91 | c.*380A>G | 3'UTR (SNP) | VAF 125/182 reads (69%) | called by muse, mutect2, varscan2
- ZNF148 | c.*2196T>C | 3'UTR (SNP) | VAF 17/151 reads (11%) | called by muse, mutect2, varscan2
- ZNF2 | chr2:95165404 G>A | 5'Flank (SNP) | VAF 44/91 reads (48%) | called by muse, mutect2, varscan2
- ZNF829 | c.*881G>A | 3'UTR (SNP) | VAF 4/10 reads (40%) | catalogued as rs1377072396; called by muse, mutect2
